Somatic mutation profile of tumor specimen TCGA-A6-3809-01B (aliquot TCGA-A6-3809-01B-04D-A270-10) from TCGA case TCGA-A6-3809, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.9 years (26,274 days).
Specimen TCGA-A6-3809-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42126ce1-4269-4f16-9d02-c8a9747938c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-3809-10A (Blood Derived Normal), aliquot TCGA-A6-3809-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b723c94-f343-4fab-b4a0-ff8ec7f0f7b6

The open-access MAF lists 1,167 somatic variants for this specimen: 903 protein-altering or splice-affecting, 245 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 620, Silent 245, Frame Shift Del 181, Frame Shift Ins 32, Nonsense Mutation 29, Splice Site 18, In Frame Del 10, Splice Region 10, Intron 7, 3'UTR 4, RNA 4, 5'Flank 3.

Variants (750 of 1,167; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.11083del p.S3695Afs*27 | Frame Shift Del (DEL) | VAF 14/127 reads (11%) | catalogued as rs1412574975, CM074695; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- B2M | c.67+1G>A p.X23_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); catalogued as CS1511368, COSV62562857; called by muse, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXE3 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755377651, COSV100624003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MTM1 | c.969del p.V324* | Frame Shift Del (DEL) | VAF 23/182 reads (13%) | catalogued as rs587783865; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN4A | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338951, COSV101438416; ClinVar: benign / pathogenic; called by muse, mutect2, varscan2
- SLC26A3 | c.332del p.F111Sfs*4 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs386833477, CD115274, COSV60639249; ClinVar: likely pathogenic; called by mutect2, varscan2
- TMPRSS6 | c.1786del p.A596Pfs*8 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs767094129, CD082210; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A1CF | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1392096112, COSV99255659; called by muse, mutect2, varscan2
- AADACL2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs369501242, COSV62932583; called by muse, mutect2, varscan2
- AAGAB | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.626); catalogued as COSV56016812; called by muse, mutect2, varscan2
- ABCA9 | c.3533G>A p.G1178D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs762341894, COSV60626437; called by muse, mutect2, varscan2
- ABCB11 | c.1915A>G p.T639A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99791847; called by muse, mutect2, varscan2
- ABCB6 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as rs1410425747, COSV99521729; called by muse, mutect2, varscan2
- ABCD2 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100429280; called by muse, mutect2, varscan2
- ABL2 | c.416A>G p.Y139C (on ENST00000502732 / NM_007314.4; = p.Y124C on NM_005158.5) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs908816677, COSV100772620; called by muse, mutect2, varscan2
- AC144573.1 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); catalogued as COSV100294404; called by muse, varscan2
- ACP1 | c.436T>C p.C146R | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755052951, COSV55243054; called by muse, mutect2, varscan2
- ACVR1B | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.396); catalogued as COSV99231366; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 53/74 reads (72%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.716T>C p.M239T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61702153; called by muse, mutect2, varscan2
- ADAM22 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55975695; called by muse, mutect2, varscan2
- ADAMTS10 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV99546708; called by muse, mutect2, varscan2
- ADAMTS15 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.936); catalogued as rs759898564, COSV100143255; called by muse, mutect2, varscan2
- ADD3 | c.2025A>C p.E675D (on ENST00000356080 / NM_001320591.2; = p.E643D on NM_001121.4) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99523300; called by muse, mutect2, varscan2
- ADGRG4 | c.7714del p.D2572Tfs*24 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as COSV54953670, COSV54960507; called by mutect2, pindel, varscan2
- ADGRL1 | c.818A>G p.D273G (on ENST00000340736 / NM_001008701.3; = p.D268G on NM_014921.5) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1387965213, COSV61566424; called by muse, mutect2, varscan2
- ADGRV1 | c.3565C>A p.L1189I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.969); catalogued as COSV101315704; called by muse, mutect2, varscan2
- ADRA1D | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.173); catalogued as rs1442709524, COSV101062945; called by muse, mutect2
- AEBP1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56256987; called by muse, mutect2, varscan2
- AEBP2 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV56862844, COSV56863268; called by muse, mutect2
- AFAP1L1 | c.529A>G p.S177G | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99695787; called by muse, varscan2
- AFF2 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs929635504, COSV99662967; called by muse, mutect2, varscan2
- AFF3 | c.3139A>C p.T1047P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100418471; called by muse, mutect2, varscan2
- AFM | c.738del p.K246Nfs*14 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | catalogued as rs985591151; called by mutect2, pindel, varscan2
- AGAP2 | c.2248T>G p.S750A (on ENST00000547588 / NM_001122772.2; = p.S414A on NM_014770.4) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as COSV57728849; called by muse, varscan2
- AGK | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100814594; called by muse, mutect2, varscan2
- AKAP11 | c.133T>C p.C45R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99213729; called by muse, mutect2, varscan2
- AL592490.1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1300701763, COSV69426007; called by muse, mutect2, varscan2
- ALDH3B1 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99141706; called by muse, varscan2
- ALG8 | c.206del p.P69Lfs*22 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as CM098505; called by mutect2, varscan2
- AMIGO2 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99873546; called by muse, mutect2, varscan2
- ANK2 | c.9682G>A p.V3228M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs141013157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs370637835; called by mutect2, varscan2
- ANK3 | c.76del p.R26Gfs*21 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as rs1373792937; called by mutect2, pindel, varscan2
- ANKH | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99414800; called by muse, mutect2, varscan2
- ANKRD11 | c.7535G>A p.R2512Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM150409, COSV99968877; called by muse, mutect2, varscan2
- ANKRD11 | c.4906G>A p.D1636N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV99968878; called by muse, mutect2, varscan2
- ANKRD26 | c.4976dup p.N1659Kfs*4 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | catalogued as rs762275496; called by mutect2, varscan2
- ANKRD44 | c.2225A>G p.Y742C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV99984582; called by muse, mutect2, varscan2
- ANO4 | c.2311T>C p.Y771H (on ENST00000392977 / NM_001286615.2; = p.Y736H on NM_178826.4) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.176); catalogued as rs1353801712, COSV54598702; called by muse, mutect2, varscan2
- ANXA6 | c.1458G>T p.E486D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1343623811, COSV62906509; called by muse, mutect2, varscan2
- AP1M1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.145); catalogued as rs749998518, COSV99358314; called by muse, mutect2, varscan2
- APBA1 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756578388, COSV99595789; called by muse, mutect2, varscan2
- APC | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs876660572, COSV57357692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs3215969; called by pindel, varscan2
- ARAP2 | c.4519A>G p.T1507A | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.715); catalogued as COSV58294469; called by muse, mutect2, varscan2
- ARHGAP20 | c.724T>A p.Y242N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99503594; called by muse, mutect2, varscan2
- ARHGAP22 | c.878A>G p.E293G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99984933; called by muse, mutect2, varscan2
- ARHGAP24 | c.1856G>A p.R619Q (on ENST00000395184 / NM_001025616.3; = p.R526Q on NM_031305.3) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.115); catalogued as rs759004152, COSV99981952; called by muse, mutect2, varscan2
- ARHGEF39 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as COSV58396980; called by muse, mutect2, varscan2
- ARHGEF4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100387879; called by muse, mutect2, varscan2
- ARL2BP | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV99536001; called by muse, mutect2, varscan2
- ARL6IP6 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV100423931; called by muse, mutect2, varscan2
- ARVCF | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99599102; called by muse, mutect2, varscan2
- ASPA | c.918A>C p.K306N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99559189; called by muse, mutect2, varscan2
- ATAD2B | c.2756C>A p.P919Q | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99477345; called by muse, mutect2, varscan2
- ATP1A2 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1392328953, COSV63405509; called by muse, mutect2, varscan2
- ATP1B4 | c.478G>A p.A160T (on ENST00000218008 / NM_001142447.3; = p.A156T on NM_012069.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.081); catalogued as rs781753966, COSV54311680; called by muse, mutect2, varscan2
- ATP2A3 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59230581; called by muse, mutect2, varscan2
- ATP2B3 | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1557015474, COSV54845611; called by muse, mutect2, varscan2
- ATP6V0A4 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV59479580; called by muse, mutect2, varscan2
- BABAM1 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV63920590, COSV63921633; called by muse, mutect2, varscan2
- BAHCC1 | c.1526A>G p.Q509R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as rs782461900, COSV57026008; called by muse, varscan2
- BANK1 | c.1969+1G>T p.X657_splice | Splice Site (SNP) | VAF 16/65 reads (25%) | catalogued as COSV100536142; called by muse, mutect2, varscan2
- BBX | c.1738A>G p.M580V | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1265533064, COSV100361297; called by muse, mutect2, varscan2
- BCAN | c.2513C>T p.T838I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100227998; called by muse, mutect2, varscan2
- BCCIP | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.02); catalogued as COSV99532950; called by muse, mutect2, varscan2
- BCORL1 | c.5042dup p.G1682Rfs*4 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | catalogued as rs768244116, COSV54407680; called by mutect2, varscan2
- BCR | c.2638C>T p.Q880* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100006314; called by muse, mutect2, varscan2
- BEND2 | c.1580A>G p.H527R | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV101191918; called by muse, mutect2, varscan2
- BET1 | c.42C>A p.N14K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99747230; called by mutect2, varscan2
- BHLHE40 | c.33del p.A12Pfs*32 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs868723963; called by mutect2, pindel
- BIRC3 | c.343T>G p.S115A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV54816374; called by muse, mutect2, varscan2
- BIRC6 | c.4612C>A p.L1538I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV101428082, COSV101429134; called by muse, mutect2, varscan2
- BMF | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV55019025; called by muse, mutect2, varscan2
- BMPR2 | c.853-1G>T p.X285_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as CS085038, CS1513975, COSV101001390; called by muse, mutect2, varscan2
- BMPR2 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.574); catalogued as rs773965156, COSV101001392; called by muse, mutect2, varscan2
- BRCA2 | c.7559G>A p.R2520Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs80358982, COSV101203989, COSV66452497; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRINP3 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1172552823, COSV100818606; called by muse, mutect2, varscan2
- BRMS1L | c.308T>C p.L103S | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99396603; called by muse, mutect2, varscan2
- BRPF1 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.434); catalogued as COSV100121178; called by muse, mutect2, varscan2
- C16orf72 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781070790, COSV59915931; called by muse, mutect2, varscan2
- C18orf25 | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV56365093; called by muse, mutect2, varscan2
- C19orf44 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs762331456, COSV99522121; called by muse, mutect2, varscan2
- C3orf20 | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99513679; called by muse, mutect2, varscan2
- C8orf34 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV61378113, COSV61380370; called by muse, mutect2, varscan2
- CABP7 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs762471805, COSV53362629; called by muse, mutect2, varscan2
- CACNA1B | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53124965; called by muse, mutect2, varscan2
- CACNA1F | c.2075G>T p.S692I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100544600; called by muse, mutect2, varscan2
- CAMK1D | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101123609; called by muse, mutect2, varscan2
- CAPN15 | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1304213547, COSV99562322; called by mutect2, varscan2
- CAPRIN1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100403709, COSV58219658; called by muse, mutect2, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs35832225; called by pindel, varscan2
- CARMIL1 | c.3193C>T p.R1065W | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs753444416, COSV61524570; called by muse, mutect2, varscan2
- CARMIL3 | c.3598G>A p.G1200R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99393273; called by mutect2, varscan2
- CARS1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs761521860, COSV99542414; called by mutect2, varscan2
- CATSPERD | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs766938408, COSV58464752; called by muse, mutect2, varscan2
- CCDC85A | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.706); catalogued as COSV101339437; called by muse, mutect2, varscan2
- CCDC91 | c.1079A>G p.Q360R | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100081586; called by muse, mutect2, varscan2
- CCHCR1 | c.1799-3del | Splice Region (DEL) | VAF 3/24 reads (13%) | catalogued as rs768163698; called by mutect2, pindel, varscan2
- CCND2 | c.318G>C p.M106I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV99714133; called by muse, mutect2, varscan2
- CCNJL | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV99979395; called by muse, mutect2, varscan2
- CDC37 | c.358A>G p.S120G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); catalogued as COSV99705742; called by muse, mutect2, varscan2
- CDC73 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100813777; called by muse, varscan2
- CDK5R2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as COSV100225875; called by muse, varscan2
- CEACAM5 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs781903049, COSV99703829; called by muse, mutect2
- CEMIP | c.3226G>A p.D1076N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1159120769, COSV54997158; called by muse, mutect2, varscan2
- CENPF | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100871626; called by muse, mutect2, varscan2
- CENPU | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs200975207; called by mutect2, varscan2
- CEP95 | c.1717T>C p.F573L | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV73609062; called by muse, mutect2, varscan2
- CFH | c.3445C>T p.R1149* | Nonsense Mutation (SNP) | VAF 22/121 reads (18%) | catalogued as rs1354315554, CM1314325, COSV66410123; called by muse, mutect2, varscan2
- CHD5 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52409971; called by muse, varscan2
- CHML | c.695A>T p.D232V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318920385, COSV100087227; called by muse, mutect2, varscan2
- CHST12 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99324400; called by muse, varscan2
- CHST15 | c.1192T>G p.L398V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100655041; called by muse, mutect2, varscan2
- CHST6 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100178344; called by muse, mutect2, varscan2
- CIB3 | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1396628976, COSV99521750; called by muse, mutect2, varscan2
- CIT | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.148); catalogued as rs141341431; called by muse, mutect2, varscan2
- CLDND1 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as COSV100360694, COSV57858727; called by muse, mutect2, varscan2
- CLIP2 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1347480501, COSV99791293; called by muse, mutect2, varscan2
- CLTCL1 | c.2735G>A p.R912Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1190343245; called by muse, varscan2
- CMBL | c.468C>T p.G156= | Splice Region (SNP) | VAF 39/140 reads (28%) | catalogued as rs1320800485, COSV56984873, COSV99686979; called by muse, mutect2, varscan2
- CNST | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs145890214; called by muse, mutect2, varscan2
- CNTNAP2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62184332; called by muse, mutect2, varscan2
- COL11A1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1386580787, COSV62181718; called by muse, mutect2, varscan2
- COL18A1 | c.4045G>A p.G1349S (on ENST00000359759 / NM_130444.3; = p.G1114S on NM_030582.4) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs775944368, COSV60590453; called by muse, mutect2, varscan2
- COL25A1 | c.1488del p.G497Efs*14 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV101211681; called by mutect2, pindel, varscan2
- COL4A4 | c.1897G>T p.G633* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100306531, COSV100307557; called by muse, mutect2, varscan2
- COL4A6 | c.330C>T p.G110= | Splice Region (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100563813; called by muse, mutect2, varscan2
- COL6A3 | c.6312C>T p.G2104= | Splice Region (SNP) | VAF 17/63 reads (27%) | catalogued as rs377074792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.4217G>T p.R1406M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV100650112; called by muse, mutect2, varscan2
- COL8A1 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53733751; called by muse, mutect2, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as COSV101232229; called by mutect2, varscan2
- COQ8A | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs200541514; called by mutect2, varscan2
- CORO7 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV99227441; called by muse, mutect2, varscan2
- CPAMD8 | c.1382C>T p.T461M (on ENST00000651564; = p.T414M on NM_015692.5) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs192285706, COSV99359195; called by mutect2, varscan2
- CPLANE1 | c.8510T>C p.V2837A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV99950151; called by muse, mutect2, varscan2
- CPXM1 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs751762428, COSV101013703; called by muse, mutect2, varscan2
- CRACD | c.3178G>A p.G1060R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as rs1336165783, COSV99948949, COSV99949367; called by muse, mutect2, varscan2
- CRB1 | c.3742T>A p.F1248I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100957771, COSV100958069; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRNKL1 | c.2290_2292del p.E764del | In Frame Del (DEL) | VAF 7/52 reads (13%) | catalogued as rs757426818; called by pindel, varscan2
- CROCC | c.4566G>T p.Q1522H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100978132; called by muse, mutect2, varscan2
- CRYZ | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as rs1037440251, COSV61717610; called by muse, mutect2, varscan2
- CSF3R | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV100117503; called by muse, mutect2, varscan2
- CSMD3 | c.7140T>G p.S2380R (on ENST00000297405 / NM_001363185.1; = p.S2276R on NM_052900.3) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99830256; called by muse, mutect2, varscan2
- CSNK1E | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV100725012; called by muse, mutect2, varscan2
- CTBP2 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs771702203, COSV100456311, COSV58333657; called by muse, mutect2, varscan2
- CYB5RL | c.931T>G p.S311A | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV55277251; called by muse, mutect2, varscan2
- CYLC1 | c.1312A>T p.K438* | Nonsense Mutation (SNP) | VAF 38/151 reads (25%) | catalogued as COSV100254361; called by muse, mutect2, varscan2
- CYP3A4 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV100315560; called by muse, mutect2, varscan2
- CYP7B1 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV59583448; called by muse, mutect2
- CYP8B1 | c.401A>G p.D134G | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV60225765; called by muse, mutect2, varscan2
- DBF4 | c.74dup p.N25Kfs*11 | Frame Shift Ins (INS) | VAF 70/207 reads (34%) | catalogued as rs762918884; called by mutect2, varscan2
- DCDC2B | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as rs1557537140, COSV59084371; called by muse, mutect2, varscan2
- DCP1B | c.992C>A p.P331H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV99767395; called by muse, mutect2, varscan2
- DCTN5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1403723804, COSV100265927; called by muse, mutect2, varscan2
- DENND11 | c.995A>T p.D332V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101530707; called by muse, mutect2, varscan2
- DENND5A | c.2917G>A p.A973T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV100064398; called by muse, mutect2, varscan2
- DEUP1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV99976971; called by muse, mutect2, varscan2
- DGKI | c.2816T>G p.L939R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV99933336; called by muse, mutect2, varscan2
- DHRS7C | c.595G>T p.A199S (on ENST00000330255 / NM_001220493.2; = p.A198S on NM_001105571.3) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV57650562; called by muse, mutect2, varscan2
- DHX16 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200255671, COSV100905169; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 31/133 reads (23%) | catalogued as rs373108427; called by mutect2, varscan2
- DIAPH2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV100232090; called by muse, mutect2, varscan2
- DIPK1C | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV59724699; called by muse, mutect2, varscan2
- DKK1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs761830028, COSV100906521, COSV64759956; called by muse, mutect2, varscan2
- DLGAP1 | c.2204G>A p.S735N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs748938600, COSV100229278; called by muse, mutect2, varscan2
- DMXL2 | c.2981C>T p.T994M | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770583176, COSV99196165; called by muse, mutect2, varscan2
- DNAH1 | c.11570T>C p.L3857P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99963727; called by muse, mutect2, varscan2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 20/86 reads (23%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH17 | c.13120G>A p.V4374M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs779904791, COSV53144946; called by muse, mutect2, varscan2
- DNAH2 | c.1460A>G p.H487R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99318056; called by muse, mutect2, varscan2
- DNAH8 | c.6695G>A p.R2232H | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59426561; called by muse, mutect2, varscan2
- DNAH9 | c.7949del p.P2650Hfs*2 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as COSV52362670; called by mutect2, varscan2
- DNAJC16 | c.1794del p.G599Afs*5 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs756910133; called by mutect2, pindel, varscan2
- DNMBP | c.1868C>A p.P623H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV100143450; called by muse, mutect2, varscan2
- DOC2A | c.191del p.P64Lfs*27 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs753153258; called by mutect2, pindel, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs782552436; called by pindel, varscan2
- DOCK4 | c.4040C>T p.A1347V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV101445596; called by muse, mutect2, varscan2
- DOP1A | c.28A>T p.S10C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV99381508; called by muse, mutect2, varscan2
- DOP1A | c.6080A>T p.N2027I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99381514; called by muse, varscan2
- DOP1B | c.4135C>T p.Q1379* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV101215216; called by muse, mutect2, varscan2
- DSC3 | c.851T>G p.I284S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100844564; called by muse, mutect2, varscan2
- DSN1 | c.183del p.G63Efs*39 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs35111724, COSV101041127; called by mutect2, pindel, varscan2
- DSPP | c.2075G>A p.S692N | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.261); catalogued as rs1280904545, COSV99216967; called by muse, mutect2, varscan2
- DUSP16 | c.1256G>A p.G419D | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV99963043; called by muse, mutect2, varscan2
- DUSP2 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs977626489, COSV99997031; called by muse, mutect2, varscan2
- DYNC1H1 | c.6770A>G p.K2257R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794703; called by muse, mutect2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs751377941; called by mutect2, varscan2
- E2F5 | c.320del p.K107Sfs*11 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | catalogued as rs761281897; called by mutect2, pindel, varscan2
- EBF1 | c.802A>T p.S268C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.228); catalogued as COSV100565547, COSV100565917; called by muse, mutect2, varscan2
- ECHDC2 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781602712, COSV64301283; called by muse, mutect2, varscan2
- EEF1E1 | c.106A>G p.N36D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV101121246; called by muse, mutect2, varscan2
- EFTUD2 | c.1846T>C p.S616P | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV101274529; called by muse, mutect2, varscan2
- EGFR | c.2999C>T p.A1000V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV51844677; called by muse, mutect2, varscan2
- EGFR | c.3454G>A p.D1152N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs368892932, COSV51814970, COSV99294960; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF2AK4 | c.281del p.N94Mfs*13 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as COSV55466133; called by pindel, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs748937918; called by mutect2, varscan2
- ELP1 | c.1670T>C p.I557T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs762639892, COSV101010364; called by mutect2, varscan2
- EMC1 | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV100916433; called by muse, mutect2, varscan2
- EMCN | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56457287; called by muse, mutect2, varscan2
- EMID1 | c.967-2A>G p.X323_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as COSV61830913; called by muse, varscan2
- EPB41L2 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382957093, COSV61353484; called by muse, mutect2, varscan2
- EPN2 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as rs1567870283, COSV100127512; called by muse, mutect2, varscan2
- ERF | c.1628T>C p.L543P | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99724580; called by muse, mutect2, varscan2
- ESYT2 | c.1715A>G p.E572G (on ENST00000613624; = p.E496G on NM_020728.3) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99276460; called by muse, mutect2
- EVC | c.2858A>G p.D953G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99381501; called by muse, mutect2, varscan2
- EXOC6B | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55553232; called by muse, mutect2, varscan2
- EZH2 | c.911A>G p.N304S (on ENST00000460911 / NM_001203247.2; = p.N309S on NM_004456.5) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.132); catalogued as COSV100235289; called by muse, mutect2, varscan2
- FAAP100 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs772327939, COSV100585301; called by mutect2, varscan2
- FAM131C | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1238560091, COSV100989674; called by muse, mutect2, varscan2
- FAM193A | c.2017del p.L673Sfs*142 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV61191975; called by mutect2, pindel, varscan2
- FAM83E | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs769111757, COSV99320181; called by mutect2, varscan2
- FAT1 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101499240; called by muse, mutect2, varscan2
- FAT2 | c.9794G>A p.R3265H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.948); catalogued as COSV55831099; called by muse, mutect2, varscan2
- FAT2 | c.5570A>G p.Q1857R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99942293; called by muse, mutect2, varscan2
- FAT4 | c.5092C>T p.R1698W | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755643759, COSV67882388; called by muse, mutect2, varscan2
- FBN2 | c.1969A>G p.T657A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV52509441; called by muse, mutect2, varscan2
- FBXL7 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100309469; called by muse, mutect2, varscan2
- FBXO44 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs183109009; called by muse, mutect2, varscan2
- FCHSD2 | c.2101A>G p.R701G | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1360601398, COSV60809151; called by muse, mutect2, varscan2
- FGD6 | c.2420G>A p.G807E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100676474; called by muse, mutect2, varscan2
- FH | c.359T>A p.I120K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845003; called by muse, mutect2, varscan2
- FIP1L1 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV60996154; called by muse, varscan2
- FLG | c.1487A>G p.H496R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.05); catalogued as COSV64235521, COSV64235730; called by muse, mutect2, varscan2
- FLRT1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs774763930, COSV55359339; called by muse, mutect2, varscan2
- FOXC1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM073073, COSV66515893; called by muse, mutect2, varscan2
- FRMD3 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs1278554883, COSV58460424; called by muse, mutect2, varscan2
- FRY | c.1205T>C p.V402A | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100969006; called by muse, mutect2, varscan2
- FURIN | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866803845, COSV99184645; called by muse, mutect2, varscan2
- FYB1 | c.1100A>G p.D367G | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV60945469; called by muse, mutect2, varscan2
- GABBR2 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1008758499, COSV52296246; called by muse, mutect2, varscan2
- GABRR2 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101298900; called by muse, mutect2, varscan2
- GANAB | c.2806G>A p.A936T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs371161821; called by muse, mutect2, varscan2
- GCNA | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as rs754484042, COSV65461912; called by muse, mutect2, varscan2
- GH2 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100236925; called by muse, mutect2, varscan2
- GJA9 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs144059875, COSV100668065; called by muse, mutect2, varscan2
- GLUD2 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100046701; called by muse, mutect2, varscan2
- GNB1L | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as rs371832244; called by muse, mutect2, varscan2
- GNRH2 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs562403614, COSV99848627; called by muse, mutect2, varscan2
- GOLGA2 | c.1868T>C p.V623A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100359755; called by muse, varscan2
- GOLGA4 | c.5512G>A p.V1838I | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.228); catalogued as rs749363115, COSV62711806; called by muse, mutect2, varscan2
- GON4L | c.2401A>C p.S801R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV55192762; called by muse, mutect2, varscan2
- GOT1L1 | c.870del p.N291Tfs*24 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs768946390; called by mutect2, pindel, varscan2
- GP2 | c.685T>G p.C229G (on ENST00000381362 / NM_001007240.3; = p.C226G on NM_001502.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56893701; called by muse, mutect2, varscan2
- GPATCH3 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs748609259, COSV100658745; called by muse, mutect2, varscan2
- GPC6 | c.1577A>C p.E526A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100988339; called by muse, mutect2, varscan2
- GPR180 | c.1102T>G p.F368V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1225464848; called by muse, varscan2
- GPS2 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100222852; called by muse, mutect2, varscan2
- GPT | c.1419del p.L474Wfs*11 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as COSV52953289; called by mutect2, pindel, varscan2
- GRID2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200889267, COSV56185846, COSV56207492; called by muse, mutect2, varscan2
- GRIK5 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as rs1190385953, COSV99490326; called by muse, varscan2
- GRIP1 | c.502G>T p.G168W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668888; called by mutect2, varscan2
- GRM3 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100862379, COSV64468189; called by muse, mutect2
- GRM5 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1254022905, COSV59588107; called by muse, mutect2, varscan2
- GSDMA | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as COSV56974283; called by muse, mutect2, varscan2
- GTF3C1 | c.4398G>T p.K1466N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100649199; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 48/208 reads (23%) | catalogued as COSV54945907; called by mutect2, varscan2
- HAP1 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV100169558; called by muse, mutect2
- HBD | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53082140, COSV99496475; called by muse, mutect2, varscan2
- HDAC8 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV101002357, COSV65227969; called by muse, mutect2, varscan2
- HDHD3 | c.331T>C p.W111R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99444862; called by muse, mutect2, varscan2
- HECTD1 | c.5053G>A p.D1685N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); catalogued as COSV101237340; called by muse, mutect2, varscan2
- HEG1 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs912548318, COSV100230313; called by muse, mutect2, varscan2
- HERC1 | c.7746A>T p.R2582S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); catalogued as COSV101496479; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 23/114 reads (20%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HHIP | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs766969894, COSV99666959; called by muse, mutect2, varscan2
- HJV | c.1024A>G p.T342A (on ENST00000336751 / NM_213653.4; = p.T229A on NM_145277.5) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs781843312; called by muse, varscan2
- HMCES | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs369963919, COSV101077279; called by mutect2, varscan2
- HRH4 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.136); catalogued as rs773632780, COSV56927767; called by muse, mutect2, varscan2
- HS3ST2 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV99757854; called by muse, mutect2
- HSD17B10 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV51447934; called by muse, mutect2, varscan2
- HSPA1L | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs745365008, COSV100989365; called by muse, mutect2, varscan2
- HSPA8 | c.1941A>T p.*647Yext*5 | Nonstop Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99914307; called by muse, mutect2, varscan2
- HYAL1 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781935297, COSV99807559; called by muse, mutect2, varscan2
- IGHE | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs782517271; called by muse, mutect2, varscan2
- IGLV1-50 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.537); catalogued as rs775889930; called by muse, mutect2, varscan2
- IL17RC | c.2161G>A p.V721M (on ENST00000295981 / NM_153461.4; = p.V635M on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs768568126, COSV55973045; called by muse, mutect2, varscan2
- IL18RAP | c.1688del p.N563Tfs*68 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as COSV99962098; called by mutect2, pindel, varscan2
- INPP5F | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as COSV100740065; called by muse, mutect2, varscan2
- INTS10 | c.1205A>G p.E402G | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.244); catalogued as COSV67604086, COSV67604620; called by muse, mutect2, varscan2
- INTS11 | c.115T>C p.F39L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV59672224; called by muse, mutect2, varscan2
- IPO7 | c.1777C>A p.Q593K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV100797805; called by muse, mutect2, varscan2
- ISG20 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as rs371941091; called by muse, mutect2, varscan2
- ITGA10 | c.1633del p.Q545Rfs*15 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs781882827; called by mutect2, varscan2
- ITGB4 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1487758259, COSV52325165; called by muse, mutect2, varscan2
- ITPR3 | c.6227G>A p.R2076H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as rs1047587727, COSV65410562; called by muse, mutect2, varscan2
- ITSN2 | c.4679-2A>G p.X1560_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100743117; called by muse, mutect2, varscan2
- JAM3 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1307104189, COSV54452091; called by muse, mutect2, varscan2
- JMJD1C | c.4841A>T p.N1614I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100550363; called by muse, mutect2, varscan2
- KANSL2 | c.896G>A p.S299N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.326); catalogued as COSV63479482; called by muse, mutect2, varscan2
- KBTBD12 | c.1438T>C p.Y480H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV59679092; called by muse, mutect2
- KCNB2 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as rs200347487, COSV73051536; called by muse, mutect2, varscan2
- KCNH3 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1233102533, COSV57791866; called by muse, mutect2, varscan2
- KCNT2 | c.2136A>C p.K712N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV99652693; called by muse, varscan2
- KCNT2 | c.2108G>A p.C703Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99652699; called by muse, varscan2
- KCTD15 | c.247A>C p.S83R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV99393110; called by mutect2, varscan2
- KCTD19 | c.721A>G p.I241V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1401191578, COSV100430814; called by muse, mutect2, varscan2
- KDM3A | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV57220679, COSV57225597; called by muse, mutect2, varscan2
- KDM4A | c.157T>G p.W53G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV100969435; called by muse, mutect2
- KDM5A | c.3278T>C p.V1093A | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101238713; called by muse, mutect2
- KDM5B | c.1832G>A p.G611D | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99350358; called by muse, mutect2, varscan2
- KDM6A | c.3472A>C p.N1158H | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65044582; called by muse, mutect2
- KIAA1328 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV99693840; called by muse, mutect2
- KIAA1549 | c.5716C>A p.P1906T (on ENST00000422774 / NM_001164665.2; = p.P1890T on NM_020910.3) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV54317086; called by muse, varscan2
- KIAA1841 | c.500A>T p.D167V | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756138624, COSV99693514; called by muse, mutect2, varscan2
- KIF18A | c.2491C>T p.R831W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs142577501; called by muse, mutect2, varscan2
- KIF26A | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100180997; called by muse, mutect2, varscan2
- KIF26B | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.641); catalogued as COSV69460731; called by muse, mutect2
- KIF2B | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264796794, COSV52133870; called by muse, mutect2, varscan2
- KIF3A | c.1706G>T p.R569M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV66414297; called by muse, mutect2
- KIF4A | c.3170A>G p.D1057G | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100979470; called by muse, mutect2
- KIT | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.036); catalogued as COSV99853763; called by muse, mutect2, varscan2
- KLHDC4 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99566251; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55870914; called by muse, varscan2
- KMT2D | c.4843C>T p.R1615* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as CM105487, COSV56420226; called by muse, varscan2
- KNSTRN | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.297); catalogued as COSV51104998; called by muse, mutect2, varscan2
- KRBA1 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99752442; called by muse, mutect2
- KRT10 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 64/160 reads (40%) | catalogued as COSV99509996; called by muse, varscan2
- KRT13 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.053); catalogued as rs1047174279, COSV55840342; called by muse, mutect2, varscan2
- KRT6A | c.43C>A p.R15S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100416866; called by muse, mutect2, varscan2
- KRT80 | c.950A>G p.K317R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV57548775; called by muse, mutect2, varscan2
- KRT84 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370280302; called by muse, mutect2, varscan2
- L1CAM | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100648987; called by muse, mutect2, varscan2
- LAMA2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1362087620, COSV101370311; called by muse, mutect2, varscan2
- LAMC3 | c.2996A>T p.D999V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV100735933; called by muse, mutect2, varscan2
- LANCL2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs759332300, COSV54650887; called by muse, mutect2, varscan2
- LANCL3 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV101065561; called by muse, mutect2, varscan2
- LARP1 | c.2027C>A p.A676D (on ENST00000518297 / NM_033551.3; = p.A599D on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100303661; called by muse, mutect2, varscan2
- LGI1 | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV101004383; called by muse, mutect2, varscan2
- LGR4 | c.2000T>G p.L667R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV100156491; called by muse, mutect2, varscan2
- LHFPL5 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV100798951; called by muse, mutect2, varscan2
- LHX9 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100435758; called by muse, mutect2, varscan2
- LINS1 | c.2263A>G p.N755D | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100130128; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 6/37 reads (16%) | catalogued as rs765287063; called by mutect2, varscan2
- LMTK2 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV51999268; called by muse, mutect2, varscan2
- LRCH2 | c.1904T>C p.M635T | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.584); catalogued as COSV57749635; called by muse, mutect2, varscan2
- LRP1B | c.5117A>G p.K1706R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV67290885; called by muse, mutect2, varscan2
- LRP3 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs762589974, COSV99472121; called by muse, mutect2, varscan2
- LRRCC1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765839225, COSV64482561; called by muse, mutect2, varscan2
- LRRIQ1 | c.3451C>A p.R1151S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101279927, COSV67832844; called by muse, mutect2, varscan2
- LRRN3 | c.615C>A p.D205E | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV57825074; called by muse, mutect2, varscan2
- LRRN4 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs762433025; called by muse, mutect2, varscan2
- LSM11 | c.589-1G>A p.X197_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV53848099; called by muse, mutect2, varscan2
- LYL1 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1281479458, COSV53400443; called by muse, mutect2, varscan2
- MAGEC1 | c.2747C>T p.A916V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776851614, COSV53578740; called by muse, mutect2, varscan2
- MAGEE1 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100819348; called by muse, mutect2, varscan2
- MANF | c.334_336del p.K112del | In Frame Del (DEL) | VAF 26/78 reads (33%) | catalogued as rs782449001; called by pindel, varscan2
- MARK4 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99488146; called by muse, mutect2, varscan2
- MAST4 | c.3133C>T p.R1045* (on ENST00000403625 / NM_001164664.2; = p.R856* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as rs367575904, COSV55146202; called by muse, mutect2, varscan2
- MAST4 | c.6812C>T p.P2271L (on ENST00000403625 / NM_001164664.2; = p.P2082L on NM_015183.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1223754877, COSV99843621; called by muse, mutect2, varscan2
- MBD5 | c.2656G>T p.G886W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101290017; called by muse, mutect2, varscan2
- MBTPS1 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100597475; called by muse, mutect2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCOLN2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs201171839, COSV52295381; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- ME2 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.555); catalogued as COSV100360712; called by muse, mutect2, varscan2
- METTL2B | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs767735930, COSV52308784; called by muse, mutect2, varscan2
- MFSD14A | c.806T>A p.L269* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | catalogued as rs749059126, COSV100924604, COSV64514301; called by muse, mutect2, varscan2
- MGST2 | c.309del p.K103Nfs*8 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | catalogued as COSV55498546; called by mutect2, pindel
- MIA2 | c.89T>A p.M30K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV54492331; called by muse, mutect2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MKI67 | c.5350A>G p.T1784A | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.672); catalogued as COSV100896380; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 27/103 reads (26%) | catalogued as rs751465048; called by mutect2, varscan2
- MLYCD | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs200750439, COSV52305058; called by muse, mutect2
- MMGT1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782610277, COSV100018457; called by muse, mutect2, varscan2
- MMP15 | c.1267T>C p.Y423H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99539372; called by muse, mutect2, varscan2
- MOV10L1 | c.1594_1596del p.E532del | In Frame Del (DEL) | VAF 16/87 reads (18%) | catalogued as rs759340800; called by mutect2, pindel, varscan2
- MPP4 | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV59630730; called by mutect2, varscan2
- MPZL1 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.426); catalogued as COSV100850335; called by muse, mutect2, varscan2
- MRPL47 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs917879069, COSV52022965; called by muse, mutect2, varscan2
- MTMR2 | c.965G>T p.R322L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60579519, COSV60581794; called by muse, mutect2, varscan2
- MTMR4 | c.1371A>C p.Q457H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV100050932; called by muse, mutect2, varscan2
- MTO1 | c.1948T>C p.S650P (on ENST00000370300 / NM_133645.3; = p.S625P on NM_012123.4) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV100940385; called by muse, mutect2
- MUC4 | c.814T>A p.S272T | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.159); catalogued as rs1332527405, COSV100640227; called by muse, mutect2, varscan2
- MYBBP1A | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99625745; called by muse, mutect2, varscan2
- MYH1 | c.4014G>C p.Q1338H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99875424; called by muse, mutect2, varscan2
- MYH3 | c.5286C>T p.D1762= | Splice Region (SNP) | VAF 7/34 reads (21%) | catalogued as rs552501098, COSV99878006; called by muse, mutect2, varscan2
- MYH8 | c.4958T>C p.L1653P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV101238348; called by muse, mutect2, varscan2
- MYO3A | c.2483G>T p.G828V | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56325791, COSV99779094; called by muse, mutect2, varscan2
- MYO5A | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.322); catalogued as rs751663129, COSV100697518; called by muse, mutect2, varscan2
- MYT1 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs1434571886, COSV60509297; called by muse, mutect2
- N4BP2L2 | c.1973del p.N658Ifs*14 (on ENST00000674422; = p.N229Ifs*14 on NM_033111.4) | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | catalogued as COSV62634500; called by mutect2, pindel, varscan2
- NAPRT | c.747G>T p.W249C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV99434944; called by muse, mutect2, varscan2
- NAT16 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as COSV100296235; called by muse, mutect2, varscan2
- NAV2 | c.2647G>A p.A883T (on ENST00000396087 / NM_001244963.2; = p.A860T on NM_145117.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.585); catalogued as rs752246924, COSV62322194; called by muse, mutect2, varscan2
- NBPF1 | c.2230G>T p.D744Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844351; called by muse, mutect2, varscan2
- NCAPD3 | c.2581G>T p.G861W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101599343; called by muse, mutect2, varscan2
- NCKAP1 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100720116; called by muse, mutect2, varscan2
- NCKAP5L | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV100258566; called by muse, mutect2
- NCOA1 | c.189A>C p.K63N | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99945677; called by muse, mutect2, varscan2
- NCOR2 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV62297238; called by muse, mutect2, varscan2
- NDRG3 | c.349G>T p.A117S (on ENST00000349004 / NM_032013.4; = p.A105S on NM_022477.4) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.178); catalogued as COSV62421788; called by muse, mutect2, varscan2
- NDUFA9 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99865447; called by muse, mutect2, varscan2
- NECTIN1 | c.1226A>G p.H409R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV99871955; called by muse, mutect2, varscan2
- NEFM | c.2719G>A p.A907T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99647129; called by muse, mutect2, varscan2
- NES | c.2395C>T p.L799F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV100957821; called by muse, mutect2, varscan2
- NETO1 | c.825T>G p.S275R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV100198461; called by muse, mutect2, varscan2
- NEURL4 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100224042, COSV59757300; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NKX6-1 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55683931; called by muse, varscan2
- NLGN1 | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs377341309, COSV100849049; called by muse, mutect2, varscan2
- NLRP13 | c.145del p.Q49Rfs*12 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs1198298310; called by mutect2, pindel, varscan2
- NLRP9 | c.2806G>C p.A936P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100242858; called by muse, mutect2, varscan2
- NOS2 | c.3365G>A p.R1122H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs748134272, COSV100569593, COSV100569695; called by muse, mutect2, varscan2
- NPAP1 | c.2981G>A p.S994N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.192); catalogued as rs757344331; called by muse, mutect2, varscan2
- NPHP3 | c.730G>T p.G244* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1310366874, COSV100446740; called by muse, mutect2, varscan2
- NPR1 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs753081607, COSV64117677; called by muse, mutect2, varscan2
- NR1H2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs772224466, COSV53800029; called by muse, varscan2
- NR4A1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767305762, COSV54482846; called by mutect2, varscan2
- NRARP | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100751944; called by muse, mutect2, varscan2
- NRXN2 | c.3991G>A p.V1331M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV99633437; called by mutect2, varscan2
- NRXN3 | c.1270C>T p.R424W (on ENST00000335750 / NM_001330195.2; = p.R51W on NM_004796.6) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748055286, COSV59755799, COSV59799087; called by muse, mutect2, varscan2
- NSD1 | c.2903A>G p.K968R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV61771801; called by muse, mutect2, varscan2
- NSUN4 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as COSV100197403; called by muse, mutect2
- NUDT19 | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67959453; called by muse, mutect2, varscan2
- NUDT3 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101466190; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs762005098; called by mutect2, pindel, varscan2
- OBSCN | c.21161C>T p.A7054V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1364964677, COSV100802898; called by muse, mutect2, varscan2
- OBSCN | c.21575G>T p.G7192V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100802900; called by muse, mutect2, varscan2
- OGFOD2 | c.917G>A p.W306* (on ENST00000228922 / NM_001304833.1; = p.W246* on NM_024623.3) | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99758595; called by muse, mutect2, varscan2
- OPA1 | c.2795T>A p.V932E (on ENST00000361510 / NM_130837.3; = p.V877E on NM_015560.3) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100655247; called by muse, mutect2, varscan2
- OPLAH | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV101470752; called by muse, mutect2, varscan2
- OR10Q1 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs777748474, COSV100372213; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2M5 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV63546824; called by mutect2, varscan2
- OR2V2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.092); catalogued as COSV100080067; called by muse, mutect2, varscan2
- OR4F6 | c.476A>G p.Q159R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61026682; called by muse, mutect2, varscan2
- OR52L1 | c.217T>G p.L73V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV59986820; called by mutect2, varscan2
- OR52N5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100399652; called by muse, mutect2, varscan2
- OR6T1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs375228674; called by muse, mutect2, varscan2
- OSBPL3 | c.2027T>G p.V676G | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100513910; called by muse, mutect2, varscan2
- OSBPL5 | c.1294T>C p.W432R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99720249; called by mutect2, varscan2
- OXNAD1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757114562; called by muse, mutect2, varscan2
- PACRGL | c.366+2T>C p.X122_splice | Splice Site (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99763990; called by muse, mutect2, varscan2
- PADI6 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as rs1300346813, COSV100639918; called by muse, mutect2, varscan2
- PAPOLA | c.2019A>C p.E673D | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV99354103; called by muse, varscan2
- PAQR4 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99233977; called by muse, mutect2, varscan2
- PARD3B | c.917T>G p.I306S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV100592933; called by muse, mutect2
- PATJ | c.3838C>T p.R1280* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as rs769605018, COSV100219318; called by muse, mutect2, varscan2
- PATL1 | c.1663A>G p.M555V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100274827; called by muse, mutect2, varscan2
- PBRM1 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV56273297; called by muse, mutect2, varscan2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2, varscan2
- PCDHGA3 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs370532251, COSV53990751; called by muse, mutect2, varscan2
- PCDHGB2 | c.892dup p.T298Nfs*9 | Frame Shift Ins (INS) | VAF 22/84 reads (26%) | catalogued as rs758957504; called by pindel, varscan2
- PDE5A | c.1742A>C p.D581A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV99308548; called by muse, varscan2
- PDE8A | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as rs748220659, COSV59637606; called by muse, varscan2
- PDIA4 | c.1819G>T p.A607S (on ENST00000286091 / NM_001371244.1; = p.A606S on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV99618410; called by muse, mutect2, varscan2
- PDS5A | c.1648G>A p.G550R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs1308211352, COSV100337267; called by muse, varscan2
- PERP | c.61A>G p.S21G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as COSV101408582; called by muse, mutect2
- PGR | c.1997G>A p.S666N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV54799912; called by muse, mutect2, varscan2
- PHKA2 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101176896; called by muse, mutect2, varscan2
- PIAS4 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV53678926; called by muse, mutect2, varscan2
- PKD2L1 | c.764del p.G255Afs*64 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as rs1169311338; called by mutect2, varscan2
- PLA2R1 | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99322618; called by muse, mutect2, varscan2
- PLCE1 | c.5666G>A p.S1889N | Missense Mutation (SNP) | VAF 3/54 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV53348647; called by muse, mutect2
- PLCH2 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs56072033; called by muse, mutect2, varscan2
- PLD2 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54005677; called by muse, mutect2, varscan2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 15/79 reads (19%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHM1 | c.2926T>C p.F976L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV69598787; called by muse, mutect2, varscan2
- PLXNA1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs777812102, COSV99302724; called by muse, mutect2, varscan2
- PLXND1 | c.5339A>G p.Q1780R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100139406; called by muse, mutect2, varscan2
- PNPLA8 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs780391824, COSV57552512; called by muse, mutect2, varscan2
- POFUT1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165070275, COSV65338489; called by muse, mutect2, varscan2
- POLE | c.3641A>C p.D1214A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100265939; called by muse, mutect2, varscan2
- POLR1G | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1197767271, COSV50004129, COSV99185215; called by muse, mutect2, varscan2
- POSTN | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101123297; called by muse, mutect2, varscan2
- PPIL4 | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53566596, COSV99481562; called by muse, mutect2, varscan2
- PPL | c.1968G>A p.A656= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as rs199762487; called by muse, mutect2
- PPP1R13B | c.131A>G p.H44R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99158216; called by muse, mutect2, varscan2
- PRDM16 | c.2848C>T p.R950* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs1294136105, COSV54599926; called by muse, mutect2, varscan2
- PRDM2 | c.2675T>C p.L892P | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99341290; called by muse, mutect2
- PREPL | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 61/497 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53216422; called by muse, mutect2, varscan2
- PRTN3 | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV99311498; called by mutect2, varscan2
- PSMD1 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 94/324 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs776542337, COSV58078450, COSV58083546; called by muse, mutect2, varscan2
- PSME2 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs150829665, COSV99395570; called by muse, mutect2, varscan2
- PSPC1 | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as rs1257955022; called by muse, mutect2, varscan2
- PTPRK | c.3040G>A p.V1014I (on ENST00000368215 / NM_001291984.2; = p.V1015I on NM_002844.4) | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1354520365, COSV100950708; called by muse, mutect2, varscan2
- PTPRT | c.3629A>G p.D1210G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100626371; called by muse, mutect2, varscan2
- PXN | c.1025A>G p.Q342R (on ENST00000228307 / NM_001080855.3; = p.Q308R on NM_002859.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV57218489; called by muse, mutect2, varscan2
- PYGO2 | c.326del p.G109Afs*52 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as COSV63757621; called by mutect2, pindel, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 86/258 reads (33%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB34 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV56386423; called by muse, mutect2, varscan2
- RAB3IL1 | c.934C>A p.R312S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100076520; called by muse, mutect2, varscan2
- RAD51AP2 | c.357del p.S120Hfs*8 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs750569378, COSV67588127; called by pindel, varscan2
- RAPGEF3 | c.743A>G p.H248R (on ENST00000389212; = p.H206R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50206052, COSV99406093; called by muse, mutect2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 61/250 reads (24%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RASSF3 | c.635A>G p.Q212R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.986); catalogued as rs1328043971, COSV99309304; called by muse, mutect2, varscan2
- RBL2 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs371003080; called by muse, mutect2, varscan2
- RBM17 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753761759, COSV101159071; called by muse, mutect2, varscan2
- RBMX2 | c.506del p.K169Rfs*26 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs1556362812; called by mutect2, varscan2
- RBPJ | c.673T>C p.L225= | Splice Region (SNP) | VAF 17/87 reads (20%) | catalogued as COSV60752494; called by muse, mutect2, varscan2
- RCN3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as COSV99571249; called by muse, varscan2
- RELN | c.10027G>A p.D3343N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.222); catalogued as rs1371498467; called by muse, varscan2
- RELN | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375752077; called by mutect2, varscan2
- RETREG1 | c.979C>T p.P327S (on ENST00000306320 / NM_001034850.2; = p.P186S on NM_019000.4) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100104065; called by muse, mutect2, varscan2
- RGS6 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 59/246 reads (24%) | catalogued as rs200924429, COSV59573357; called by muse, mutect2, varscan2
- RNASEL | c.1930dup p.M644Nfs*3 | Frame Shift Ins (INS) | VAF 30/132 reads (23%) | catalogued as rs1192139971; called by mutect2, varscan2
- RND1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs267603489, COSV59045087; called by muse, mutect2, varscan2
- RNF113B | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774767836, COSV57434757; called by muse, mutect2, varscan2
- RNF139 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99413278; called by muse, mutect2, varscan2
- RNF39 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs142632327; called by muse, mutect2, varscan2
- RNF41 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV61504359; called by muse, mutect2, varscan2
- RPA4 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100232092; called by muse, mutect2, varscan2
- RPH3A | c.611-1G>T p.X204_splice (on ENST00000389385 / NM_001143854.2; = p.X200_splice on NM_014954.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/70 reads (26%) | catalogued as COSV101231795; called by muse, mutect2, varscan2
- RPL34 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101158421; called by muse, varscan2
- RRAS | c.635del p.G212Afs*22 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV55868923; called by pindel, varscan2
- RRBP1 | c.2509G>T p.E837* (on ENST00000377813 / NM_001365613.2; = p.E404* on NM_004587.3) | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV55699297; called by muse, mutect2, varscan2
- RREB1 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58557005; called by muse, mutect2, varscan2
- RS1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1402116265, CM136243, COSV66107582; called by muse, mutect2, varscan2
- RSPH10B | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 91/526 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1562555346, COSV100382772; called by muse, mutect2, varscan2
- RTF1 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV67477976; called by muse, mutect2, varscan2
- RUNX2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as rs147009083, COSV61844130; called by muse, mutect2, varscan2
- RXFP1 | c.1820A>G p.H607R | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV100313655; called by muse, mutect2, varscan2
- RYR1 | c.4072G>C p.G1358R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV100615307; called by muse, mutect2, varscan2
- RYR2 | c.3371C>T p.P1124L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs779640835, COSV100769203, COSV63662051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.13982A>G p.Y4661C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100769205; called by muse, mutect2, varscan2
- SAFB2 | c.1429A>G p.M477V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV99385563; called by muse, mutect2, varscan2
- SAMD9L | c.2668A>G p.M890V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV100560550; called by muse, mutect2
- SCAF4 | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); catalogued as COSV99741234; called by muse, mutect2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCAF8 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs749076389, COSV100914024; called by mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs757259031; called by mutect2, varscan2
- SCLY | c.311C>T p.T104I (on ENST00000651534; = p.T96I on NM_016510.7) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99615490; called by muse, mutect2, varscan2
- SCN1B | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as rs764539405, COSV52883367; called by muse, mutect2, varscan2
- SCN3A | c.4757C>T p.T1586I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as rs778468833, COSV99326396; called by muse, varscan2
- SCN7A | c.2480T>C p.I827T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV101313153; called by muse, mutect2
- SDK2 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs572942777, COSV66181469, COSV66185292; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SELL | c.183G>A p.M61I (on ENST00000650983; = p.M48I on NM_000655.5) | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV52551564; called by muse, mutect2
- SERPINB9 | c.487A>G p.N163D | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV101046538; called by muse, mutect2, varscan2
- SERPINF1 | c.397del p.Q133Rfs*18 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as COSV99628862; called by mutect2, pindel, varscan2
- SERTAD1 | c.550A>C p.N184H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100781675; called by muse, mutect2, varscan2
- SF3B1 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as COSV100134295; called by muse, mutect2, varscan2
- SFMBT1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1389189429, COSV99965938; called by muse, mutect2, varscan2
- SHARPIN | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs377598498; called by mutect2, varscan2
- SHPRH | c.4093C>T p.R1365C (on ENST00000275233 / NM_001042683.3; = p.R1369C on NM_173082.3) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378058905, COSV51609268; called by muse, mutect2, varscan2
- SIK2 | c.1615A>G p.M539V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100516092; called by muse, mutect2, varscan2
- SKA3 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs146011474; called by muse, mutect2, varscan2
- SLC12A6 | c.617del p.L206Yfs*28 (on ENST00000354181 / NM_001365088.1; = p.L155Yfs*28 on NM_005135.2) | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as rs916571899; called by pindel, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC16A1 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); catalogued as rs1001233585, COSV100855907; called by muse, mutect2
- SLC25A3 | c.607G>A p.A203T (on ENST00000228318 / NM_005888.3; = p.A202T on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/245 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV51845053; called by muse, mutect2
- SLC29A3 | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs779031920, COSV100928452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC2A9 | c.1575G>T p.E525D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV99304336; called by muse, mutect2, varscan2
- SLC30A3 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.627); catalogued as COSV99273560; called by muse, mutect2
- SLC30A9 | c.1289T>C p.V430A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100048085; called by muse, mutect2, varscan2
- SLC35B3 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as COSV100217246; called by muse, mutect2, varscan2
- SLC35G3 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs746447506, COSV52011086; called by muse, mutect2, varscan2
- SLC43A2 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs200135342, COSV100024844; called by muse, mutect2, varscan2
- SLC4A10 | c.2207C>T p.T736I (on ENST00000446997 / NM_001354461.2; = p.T706I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99763265; called by muse, mutect2, varscan2
- SLC5A6 | c.1888C>T p.L630F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.296); catalogued as rs1480675291, COSV100143179; called by muse, mutect2
- SLC5A7 | c.1678A>G p.K560E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs770906251, COSV99886493; called by mutect2, varscan2
- SLC7A2 | c.504del p.F168Lfs*9 (on ENST00000494857 / NM_001370338.1; = p.F208Lfs*9 on NM_003046.6) | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | catalogued as rs780138939; called by mutect2, pindel, varscan2
- SLC9A5 | c.2080+1G>A p.X694_splice | Splice Site (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100237199; called by muse, mutect2, varscan2
- SLCO1B3 | c.977del p.F326Sfs*4 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | catalogued as rs769005039, COSV53944787; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SLF1 | c.2333A>G p.K778R | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV99475754; called by muse, mutect2, varscan2
- SMC5 | c.2747A>G p.Q916R | Missense Mutation (SNP) | VAF 90/331 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100747023; called by muse, mutect2, varscan2
- SNAPC4 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as rs370621243; called by muse, mutect2, varscan2
- SNTG1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52440196; called by muse, mutect2
- SNX13 | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV101285079; called by muse, mutect2, varscan2
- SNX16 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV62034775; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs768873484; called by mutect2, varscan2
- SON | c.4543G>T p.A1515S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99277548; called by muse, mutect2, varscan2
- SORL1 | c.4294G>A p.V1432M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs201868665, COSV99493383; called by muse, varscan2
- SORL1 | c.4334C>T p.A1445V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV52764254; called by muse, varscan2
- SOX11 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100430952, COSV58983614; called by muse, mutect2, varscan2
- SOX9 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM141441, COSV99818301; called by muse, mutect2, varscan2
- SP2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1285394084, COSV65063984; called by muse, mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs371303534; called by mutect2, varscan2
- SPATA20 | c.1616T>C p.L539P (on ENST00000356488 / NM_001258372.1; = p.L555P on NM_022827.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99135730; called by muse, mutect2, varscan2
- SPOCK3 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.183); catalogued as COSV62728586; called by muse, mutect2, varscan2
- SPTLC2 | c.331T>G p.F111V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99377370; called by muse, mutect2, varscan2
- SRFBP1 | c.707dup p.N236Kfs*5 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | catalogued as rs751748506; called by mutect2, varscan2
- SRGAP1 | c.1429A>G p.T477A | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as COSV100754475; called by muse, mutect2, varscan2
- SRMS | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs564747393, COSV99421263; called by muse, mutect2, varscan2
- SSB | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1308557439, COSV53626414; called by muse, mutect2, varscan2
- SSC4D | c.188del p.G63Afs*32 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs756615057; called by mutect2, varscan2
- SSUH2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as rs1344306423, COSV100435698; called by muse, mutect2, varscan2
- ST8SIA1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs1468430662, COSV53952769; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAB1 | c.6835C>T p.R2279W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs993011575; called by muse, varscan2
- STAB2 | c.5209T>C p.S1737P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as COSV101185789; called by muse, mutect2, varscan2
- STAT5B | c.1749dup p.H584Tfs*8 | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | catalogued as rs1202978138; called by mutect2, varscan2
- STEAP4 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57329145; called by muse, mutect2, varscan2
- STIP1 | c.10-2A>G p.X4_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | catalogued as COSV59438795; called by muse, mutect2, varscan2
- STRADA | c.997C>T p.R333W (on ENST00000336174 / NM_001363786.1; = p.R296W on NM_153335.6) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs761989598, COSV51992441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STRN3 | c.1796del p.N599Ifs*42 (on ENST00000357479 / NM_001083893.2; = p.N515Ifs*42 on NM_014574.4) | Frame Shift Del (DEL) | VAF 27/155 reads (17%) | catalogued as COSV62579233; called by mutect2, pindel, varscan2
- STT3B | c.1391T>A p.L464* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV99854225; called by muse, mutect2, varscan2
- STX2 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as rs149127129, COSV55434347; called by muse, mutect2, varscan2
- STYXL2 | c.3346C>T p.R1116W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs376045213; called by muse, mutect2, varscan2
- SULF1 | c.2218A>G p.S740G | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99482677; called by muse, mutect2, varscan2
- SUSD1 | c.373+2T>C p.X125_splice | Splice Site (SNP) | VAF 7/126 reads (6%) | catalogued as COSV100813250; called by muse, mutect2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/85 reads (40%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYNE1 | c.16676C>T p.A5559V (on ENST00000367255 / NM_182961.4; = p.A5488V on NM_033071.3) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV99558900; called by muse, mutect2, varscan2
- SYT14 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV99654931; called by muse, mutect2, varscan2
- TAB2 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99644691; called by muse, mutect2, varscan2
- TAF15 | c.853del p.E285Rfs*41 (on ENST00000605844 / NM_139215.3; = p.E282Rfs*41 on NM_003487.4) | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs1568274282; called by mutect2, pindel, varscan2
- TANGO2 | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as COSV59293525; called by muse, mutect2, varscan2
- TBC1D17 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.653); catalogued as COSV99680540; called by muse, mutect2, varscan2
- TBC1D2 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs373402118, COSV59787376; called by muse, mutect2, varscan2
- TBC1D20 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV100830481; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D25 | c.1538T>G p.L513R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100952124; called by muse, mutect2, varscan2
- TBRG4 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs1322371274, COSV99345328; called by muse, mutect2, varscan2
- TBX19 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100892341; called by muse, mutect2, varscan2
- TBX3 | c.1124G>A p.S375N (on ENST00000257566 / NM_016569.4; = p.S355N on NM_005996.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99983637; called by muse, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 41/148 reads (28%) | catalogued as rs758822980; called by mutect2, varscan2
- TDRD9 | c.2642C>A p.P881H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV100174916; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs763321097; called by mutect2, varscan2
- TECRL | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs779934093, COSV67086444, COSV67089614; called by muse, mutect2, varscan2
- TERB2 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs771829581, COSV100546544; called by muse, mutect2, varscan2
- TEX10 | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs372772500; called by muse, mutect2, varscan2
- TFAP2D | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV50458021, COSV99145824; called by muse, mutect2, varscan2
- TFEB | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV100026092; called by muse, mutect2, varscan2
- TLL1 | c.2048C>A p.S683Y | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99286792, COSV99288641; called by muse, mutect2, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs760930120; called by mutect2, varscan2
- TMEM192 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs954870948, COSV60585058; called by muse, mutect2, varscan2
- TMEM225 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100902780; called by muse, mutect2, varscan2
- TMEM37 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs747500777, COSV99191547; called by muse, mutect2, varscan2
- TMEM51 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV101051507; called by muse, mutect2, varscan2
- TMEM54 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907973869; called by muse, mutect2
- TMPRSS11F | c.69A>C p.Q23H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.445); catalogued as COSV62466183, COSV62467201; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs777732715, COSV64423257; called by muse, mutect2, varscan2
- TNFRSF8 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as rs959447884, COSV99821299; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNNI3K | c.150-1G>A p.X50_splice | Splice Site (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100436216; called by muse, mutect2, varscan2
- TNNT1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV99402795; called by muse, mutect2, varscan2
- TNPO1 | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1268132390, COSV61520165; called by muse, mutect2, varscan2
- TNPO3 | c.644A>G p.D215G | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.439); catalogued as COSV99602740; called by muse, mutect2, varscan2
- TNR | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1178257247, COSV54883758; called by muse, mutect2, varscan2
- TNS3 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs958026760, COSV60786219, COSV60790280; called by muse, mutect2, varscan2
- TOGARAM2 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101091016; called by muse, mutect2, varscan2
- TP53BP1 | c.3977G>A p.S1326N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99780198; called by muse, mutect2, varscan2
- TRIM23 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51549931, COSV99139920; called by muse, mutect2, varscan2
- TRIM69 | c.859C>A p.L287M (on ENST00000329464 / NM_182985.5; = p.L128M on NM_080745.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs761506234, COSV57803591; called by muse, mutect2, varscan2
- TRIM72 | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100265377; called by mutect2, varscan2
- TRPC3 | c.410C>T p.T137M (on ENST00000379645 / NM_001366479.2; = p.T64M on NM_003305.2) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV53373566; called by muse, mutect2, varscan2
- TSHZ2 | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100295777; called by muse, mutect2, varscan2
- TTC17 | c.2587G>T p.G863C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99235078; called by muse, mutect2, varscan2
- TTC37 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100706496; called by muse, mutect2, varscan2
- TTF2 | c.2588+2T>C p.X863_splice | Splice Site (SNP) | VAF 34/86 reads (40%) | catalogued as COSV101037369; called by muse, mutect2, varscan2
- TTN | c.78011G>A p.R26004H (on ENST00000591111; = p.R18580H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | PolyPhen probably damaging (0.998); catalogued as rs766522109, COSV100603504; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.50291G>A p.R16764H (on ENST00000591111; = p.R9340H on NM_003319.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | PolyPhen probably damaging (0.998); catalogued as rs771921519, COSV100603507, COSV100630510; called by muse, mutect2, varscan2
- TTN | c.31787A>C p.K10596T (on ENST00000591111; = p.K9669T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | PolyPhen benign (0.196); catalogued as COSV100603510; called by muse, mutect2, varscan2
- TUSC3 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755902777, COSV65880110; called by muse, mutect2, varscan2
- TXLNA | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs564542437, COSV101009826; called by muse, mutect2, varscan2
- UAP1L1 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs751667578, COSV64306458; called by muse, mutect2, varscan2
- UBA2 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55828644; called by muse, mutect2, varscan2
- UBA3 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.291); catalogued as COSV100734658; called by muse, mutect2, varscan2
- UBE2O | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.387); catalogued as rs774723942, COSV100084377; called by muse, mutect2, varscan2
- UBE2O | c.1052A>G p.E351G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100084380; called by muse, varscan2
- UBP1 | c.471A>G p.I157M | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as COSV99372624; called by muse, mutect2, varscan2
- UBQLN4 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.561); catalogued as rs1343830764, COSV64149097; called by muse, mutect2, varscan2
- UBR5 | c.7484C>T p.T2495I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs769565738, COSV99640304; called by muse, mutect2, varscan2
- UCHL1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748642283, COSV99449341; called by muse, mutect2, varscan2
- UFSP1 | c.196del p.D66Tfs*14 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs751446699; called by mutect2, pindel, varscan2
- UGGT1 | c.2543T>C p.I848T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52138040; called by muse, mutect2
- UHRF1BP1L | c.4081+2T>C p.X1361_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99691350; called by muse, mutect2, varscan2
- ULK2 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs780072901, COSV100860707; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs760213136; called by mutect2, varscan2
- UQCRFS1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201777347, COSV59184824; called by muse, mutect2, varscan2
- UQCRFS1 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV59184832; called by muse, mutect2, varscan2
- USP11 | c.1849del p.L617Sfs*19 (on ENST00000218348; = p.L574Sfs*19 on NM_001371072.1) | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as COSV54474231; called by mutect2, pindel, varscan2
- USP28 | c.1157T>C p.L386P | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99134888; called by muse, mutect2
- USP6NL | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1190896155, COSV53209292; called by muse, mutect2
- USPL1 | c.3162G>T p.E1054D | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV99687149; called by muse, mutect2, varscan2
- VAT1L | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100213293; called by muse, mutect2, varscan2
- VCPIP1 | c.105dup p.L36Afs*51 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs755078234; called by mutect2, varscan2
- VCPKMT | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as rs780360587, COSV53570228; called by muse, mutect2, varscan2
- VEGFC | c.487_488insT p.G163Vfs*6 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | catalogued as COSV99709663; called by mutect2, pindel, varscan2
- VGLL3 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.549); catalogued as COSV101051860; called by muse, mutect2, varscan2
- VPS45 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as rs782545355, COSV64886979; called by muse, mutect2, varscan2
- VPS8 | c.3217G>A p.A1073T (on ENST00000625842 / NM_001349294.1; = p.A1071T on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1366489095, COSV54980292, COSV54996565; called by muse, mutect2, varscan2
- VSIR | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99820080; called by muse, mutect2, varscan2
- VWA7 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100791794; called by muse, mutect2, varscan2
- WARS2 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753188889, COSV99346170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDFY3 | c.6758-1G>T p.X2253_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99882894; called by muse, mutect2, varscan2
- WDR24 | c.431G>A p.W144* (on ENST00000248142; = p.W82* on NM_032259.4) | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99555556; called by muse, mutect2, varscan2
- WDR41 | c.1101dup p.N368* | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs748110033; called by mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBTB11 | c.2016G>T p.K672N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.113); catalogued as COSV100465302; called by muse, mutect2, varscan2
- ZBTB39 | c.1799C>A p.P600H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV55629181; called by muse, varscan2
- ZC4H2 | c.660del p.K221Sfs*11 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as COSV100565069, COSV62003602; called by mutect2, pindel, varscan2
- ZDBF2 | c.5624del p.K1875Rfs*39 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as rs770232797, COSV65623567; called by mutect2, varscan2
- ZFP90 | c.1780del p.T594Pfs*57 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as rs747260313; called by mutect2, varscan2
- ZFYVE26 | c.2371A>G p.T791A | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.615); catalogued as COSV100720266; called by muse, mutect2, varscan2
- ZFYVE28 | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99342672; called by muse, mutect2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF180 | c.435T>G p.D145E | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV99659722; called by muse, mutect2, varscan2
- ZNF184 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778315131, COSV99279515; called by muse, varscan2
- ZNF320 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as COSV101206849; called by muse, mutect2, varscan2
- ZNF330 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.333); catalogued as rs1480476689, COSV53707059; called by muse, mutect2, varscan2
- ZNF431 | c.3+2T>C p.X1_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100218609; called by muse, mutect2, varscan2
- ZNF431 | c.842T>G p.I281S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs12973294, COSV100218610; called by muse, mutect2, varscan2
- ZNF462 | c.6015G>A p.G2005= | Splice Region (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99471333; called by muse, varscan2
- ZNF546 | c.934C>A p.R312S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.505); catalogued as rs772771629, COSV100713394; called by muse, mutect2, varscan2
- ZNF566 | c.247T>C p.C83R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.754); catalogued as COSV101091321; called by muse, mutect2, varscan2
- ZNF576 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100338103; called by muse, mutect2, varscan2
- ZNF616 | c.2024A>C p.N675T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV100348249; called by muse, mutect2, varscan2
- ZNF622 | c.1331A>G p.D444G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200793188; called by mutect2, varscan2
- ZNF680 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs147253391; called by mutect2, varscan2
- ZNF688 | c.717dup p.R240Afs*19 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as rs757983438; called by pindel, varscan2
- ZNF704 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.911); catalogued as COSV100589434; called by muse, mutect2, varscan2
- ZNF787 | c.424C>G p.R142G | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV54419090, COSV99555431; called by muse, mutect2
- ZNF92 | c.1017del p.K339Nfs*23 (on ENST00000328747 / NM_152626.4; = p.K270Nfs*23 on NM_007139.4) | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | catalogued as COSV100166046; called by mutect2, pindel, varscan2
- ZSCAN31 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.268); catalogued as COSV60180498, COSV60180760; called by muse, mutect2, varscan2
- ABCC1 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- ADAT1 | c.1071dup p.G358Rfs*17 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- ADCY10 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2
- ADNP | c.64del p.I22Yfs*14 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by pindel, varscan2
- AFG1L | c.448del p.Y150Mfs*6 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- AGPAT5 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AKR1C8P | c.378+2T>C p.X126_splice | Splice Site (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- AOPEP | c.507A>T p.K169N | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- APC | c.2544dup p.D849Rfs*2 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- APC2 | c.445_447del p.E149del | In Frame Del (DEL) | VAF 25/65 reads (38%) | called by pindel, varscan2
- APP | c.698_700del p.E233del | In Frame Del (DEL) | VAF 9/28 reads (32%) | called by pindel, varscan2
- ARHGEF6 | c.1910_1911del p.R637Kfs*10 | Frame Shift Del (DEL) | VAF 20/184 reads (11%) | called by pindel, varscan2
- ARSF | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, varscan2
- ARSL | c.14A>G p.H5R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2
- ATXN7 | c.2340del p.T781Pfs*11 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- BFAR | c.1052G>T p.W351L | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.386); called by muse, mutect2
- BLZF1 | c.962dup p.I322Dfs*6 | Frame Shift Ins (INS) | VAF 19/54 reads (35%) | called by mutect2, varscan2
- BMPR2 | c.1618del p.I540Lfs*24 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- BNIP3 | c.331dup p.I111Nfs*8 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- C17orf98 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- C1QTNF9 | c.243del p.V82Lfs*99 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- C7orf25 | c.1107del p.A370Pfs*4 | Frame Shift Del (DEL) | VAF 47/197 reads (24%) | called by mutect2, pindel, varscan2
- CA14 | c.360del p.S121Qfs*27 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- CAMSAP2 | c.3155del p.K1052Rfs*43 (on ENST00000236925 / NM_001297707.2; = p.K1041Rfs*43 on NM_203459.3) | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
417 further variants in this file (153 protein-altering or splice-affecting, 245 silent, 19 other) are not listed here.
